Surgical pathology report (de-identified scan), TCGA case TCGA-KR-A7K8, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University Of Michigan, specimen TCGA-KR-A7K8-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 2

BIRTHDATE:

SEX: M

ADM DATE:

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0

OPER DATE:

JW 8/27/13

PROCEDURE: SPHS

Hepatocellular carcinoma. Clinical Diagnosis: Hepatocellular carcinoma.
Operative Procedure: Open right hepatic lobectomy, intraoperative ultrasound.

PROCEDURE: SPGD

1. "Gallbladder" Received in a tall small container filled with formalin is a 7.5 x 1.8 x 1.2 cm intact, unremarkable gallbladder. Cystic duct measures 0.1 cm in diameter and is probe patent. The gallbladder wall has an average thickness of 0.2 cm.

1A. Standard gallbladder sections.

2. "Right lobe of liver gross margins" Received fresh for gross margin evaluation in a large container is a 1045 gm, 17 x 16 x 6.5 cm right lobe of liver. Specimen is remarkable for a 9.5 x 7.5 x 6.9 cm mass with yellow-tan, focally hemorrhagic, lobulated, solid cut surfaces and pushing borders which focally abut the blue inked margin of resection as well as the overlying Glisson's capsule.

2A-G. Mass to include closest resection margin in 2A-D, overlying capsule in 2E, and adjacent uninvolved parenchyma in 2F.

3. "Additional medial margin." Received in formalin in a tall small container is a 4.5 x 3.0 x 0.8 cm, unoriented portion of hepatic parenchyma. One aspect is tan and red variegated and shaggy and the opposing aspect is dark red-brown, shaggy and cauterized and bears multiple staples. Staples are removed and specimen is serially sectioned.

3A-E.

Note: Entire specimen cannot be submitted due to the presence of numerous staples.

INTRAOPERATIVE GROSS MARGINS:

=====

Less than 1 mm from resection margin.

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 3

BIRTHDATE:

SEX: M

ADM DATE:

OPER DATE:

PROCEDURE: SPMI

LIVER: HEPATOCELLULAR CARCINOMA

=====

WAS THE TUMOR PREVIOUSLY TREATED?: Yes, ~90% of tumor is viable.

*Per TSS - portal vein embolization,
no tx. BCR*

TUMOR TYPE: Treated

SINGLE OR MULTIPLE MASSES: Single

MAXIMUM DIAMETER OF LARGEST MASS: 9.5 cm

ARE THE MARGINS OF RESECTION FREE OF TUMOR?: Yes

VASCULAR INVASION?: No

INVASION THROUGH THE CAPSULE TO THE SEROSAL SURFACE?: No

LYMPH NODE METASTASES?: No

DISTANT METASTASES?: Unknown.

IS THE LIVER CIRRHOTIC?: No

ypT1 NX MX

PROCEDURE: SPDX

1-3. Gallbladder and right lobe of liver, resections: Hepatocellular carcinoma arising in a non-cirrhrotic liver. Margins free. Unremarkable gallbladder. See TEMPLATE above.

I, the signing staff pathologist, have personally examined and interpreted the slides from this case.

FC:88307(2), 88304

Source: NCI Genomic Data Commons file 0fcb37a5-2f7d-44a8-9c21-b1e5379ca118 (TCGA-KR-A7K8.9B449A83-1172-4EE0-9337-27BD5D3ECF4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).